Gene-level copy-number profile of tumor specimen TCGA-02-0048-01A from TCGA case TCGA-02-0048, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 80.2 years (29,299 days).
Specimen TCGA-02-0048-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.e7dcdd6d-aa28-48e9-949c-af8da8cdf5c0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-02-0048-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/03108cf2-02c0-44af-8843-5e45658c98b1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 56; copy number 1: 15,603; copy number 2: 43,587; copy number 3: 83; copy number 4: 2; copy number 5: 14; copy number 6: 66; copy number 7: 10; copy number 8: 2; copy number 10: 241; copy number 12: 71; copy number 23: 82.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-02-0048-01): tumor purity 0.88, ploidy 1.92, whole-genome doublings 0 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 56 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–25,089,151, 35 genes: MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL161628.1, AL365204.1, AL365204.2, AL365204.3, AL513317.1, IZUMO3, AL353811.1, RMRPP5, RN7SKP120.
- chr9:25,937,912–26,644,595, 3 genes (within-gene range 0–1): FAM71BP1, AL353753.1, AL442639.1.
- chr9:27,245,680–27,297,150, 2 genes: LINC00032, EQTN.
- chr9:27,829,276–28,888,955, 8 genes: AL360014.1, AL353746.1, LINGO2, AL451124.1, AL445526.1, KCTD10P1, MIR876, MIR873.
- chr9:29,824,742–30,575,012, 3 genes: ME2P1, LINC01242, SLC4A1APP1.
- chr9:31,253,901–31,645,160, 5 genes: SLC25A6P2, LINC01243, MTATP6P30, MTCO3P30, HMGB3P23.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 486 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:176,415,439–188,890,671, 262 genes, copy number 6–10 (within-gene range 2–10) (broad region; genes not listed).
- chr7:53,862,233–57,837,046, 159 genes, copy number 7–23 (broad region; genes not listed).
- chr7:66,376,044–67,239,519, 35 genes, copy number 6: LINC00174, GTF2IP9, SKP1P1, AC008267.2, AC008267.4, AC008267.7, AC008267.5, AC008267.6, GS1-124K5.4, AC008267.1, AC008267.3, AC006001.3, AC006001.4, SAPCD2P3, AC006001.1, RPL35P5, KCTD7, AC027644.4, AC006001.2, RABGEF1, AC027644.3, AC027644.2, GTF2IRD1P1, AC027644.1, GTF2IP23, RNU6-1254P, LINC02604, AC073335.1, Metazoa_SRP, TMEM248, RN7SL43P, SBDS, TYW1, AC073089.1, MIR4650-1.
- chr7:78,347,142–78,448,999, 2 genes, copy number 6: RPL13AP17, AC006043.1.
- chr7:92,528,773–92,917,187, 8 genes, copy number 6 (within-gene range 2–6): RBM48, AC005156.1, FAM133B, CDK6, AC000065.2, AC000065.1, RNU6-10P, CDK6-AS1.
- chr7:114,613,787–114,653,455, 2 genes, copy number 7: RNA5SP238, MIR3666.
- chr7:118,880,103–118,951,259, 2 genes, copy number 7: GTF3AP6, AC092098.1.
- chr7:129,434,432–129,952,960, 13 genes, copy number 5 (within-gene range 2–5): STRIP2, SNRPGP3, RNU1-72P, SMKR1, AC078846.1, NRF1, RNA5SP244, AC084864.2, MIR182, MIR96, MIR183, AC084864.1, UBE2H.
- chr7:129,954,693–129,954,794, 1 gene, copy number 5: Y_RNA.
- chr8:75,302,296–75,377,014, 2 genes, copy number 8: HIGD1AP6, PKMP4.

Autosomal genes at a single copy (total copy number 1): 13,222. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
